Surgical pathology report (de-identified scan), TCGA case TCGA-50-8457, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-8457-01A (Primary Tumor).

[page 1 of 4]
FINAL DIAGNOSIS:

Collection Date: [REDACTED]

Summary Statement

The right upper lobe contains a 3 cm adenocarcinoma with angiolymphatic invasion. Visceral pleural invasion is absent. All submitted lymph nodes are negative for carcinoma. [pT1bN0 AJCC [REDACTED]

PART 1: LYMPH NODE, LEVEL 9, BIOPSY –
PROFILES OF LYMPH NODE, NEGATIVE FOR MALIGNANCY.

PART 2: LYMPH NODE, LEVEL 11, BIOPSY –
PROFILES OF LYMPH NODE, NEGATIVE FOR MALIGNANCY.

PART 3: LYMPH NODE, LEVEL 10, BIOPSY –
PROFILES OF LYMPH NODE, NEGATIVE FOR MALIGNANCY.

PART 4: LYMPH NODE, LEVEL 4, BIOPSY –
PROFILES OF LYMPH NODE, NEGATIVE FOR MALIGNANCY.

PART 5: LYMPH NODE, LEVEL 5, BIOPSY –
PROFILES OF LYMPH NODE, NEGATIVE FOR MALIGNANCY.

PART 6: LUNG, RIGHT UPPER LOBE, LOBECTOMY –
A. INVASIVE ADENOCARCINOMA, ACINAR PREDOMINANT (90% ACINAR, 10% PAPILLARY).
a. SIZE OF TUMOR: 3.0 X 2.7 X 2.2 CM.
b. SIZE OF INVASIVE COMPONENT: 3.0 X 2.7 X 2.2 CM.
c. ANGIOLYMPHATIC INVASION PRESENT.
d. VISCERAL PLEURAL INVASION NOT IDENTIFIED.
e. SURGICAL MARGIN NEGATIVE FOR TUMOR (BY 2.5 CM).
f. PATHOLOGIC STAGE: T1bN0 (AJCC [REDACTED])

B. THREE INTRAPULMONARY PERIBRONCHIAL LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/3).

COMMENT:

Molecular testing has been requested and will be reported subsequently. The previous fine needle aspiration from [REDACTED] demonstrated the tumor cells to be reactive with antibodies directed against TTF-1 and Napsin, supporting a lung origin of this tumor.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY LUNG TUMORS**

TUMOR LOCATION:	Right Upper Lobe
PROCEDURE:	Lobectomy
TUMOR SIZE:	Maximum dimension: 3 cm Minor dimension: 2.7 cm
GROSS SATELLITES:	Number of gross satellite lesions: 0
TUMOR TYPE:	Invasive adenocarcinoma, Dominant Pattern: Acinar
HISTOLOGIC GRADE:	G2, Moderately differentiated
EXTRAPULMONARY EXTENSION/INVASION OF TUMOR:	None identified (PLO)
ANGIOLYMPHATIC INVASION:	Yes
TUMOR NECROSIS:	< or = to 50%
SURGICAL MARGIN INVOLVEMENT:	No
SURGICAL MARGIN SITE:	Distance of invasive tumor to closest margin: 25 mm
INFLAMMATORY(DESMOPLASTIC) REACTION:	Mild
N1 LYMPH NODES:	Number of N1 lymph nodes positive: 0 Number of N1 lymph nodes examined: 5
N2 LYMPH NODES:	Number of N2 lymph nodes positive: 0 Number of N2 lymph nodes examined: 3
UNDERLYING DISEASE(S):	Emphysema, Smokers bronchiolitis
T STAGE, PATHOLOGIC:	pT1b
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	Not applicable
ANCILLARY STUDIES:	Histochemical stains, FISH studies, Molecular studies

COMPREHENSIVE THERANOSTIC SUMMARY**IMMUNOHISTOCHEMISTRY****IN SITU HYBRIDIZATION / FISH**

ALK rearrangement:	NEGATIVE
C-MET amplification:	NEGATIVE

MOLECULAR ANATOMIC PATHOLOGY

EGFR exon 18 mutation:	NEGATIVE
EGFR exon 19 mutation:	NEGATIVE
EGFR exon 20 mutation:	NEGATIVE
EGFR exon 21 mutation:	NEGATIVE
BRAF exon 15 mutation (PCR):	NEGATIVE
KRAS exon 2 (codons 12, 13) mutation (PCR):	POSITIVE (mutation type: G12A)
KRAS exon 3 (codon 61) mutation (PCR):	NEGATIVE

[page 2 of 4]
In Situ Procedure

Interpretation

PROBE: LSI ALK Dual-Color Break-apart Probe 2p23

ALK FISH STUDIES PERFORMED ON THE ADENOCARCINOMA ARE NEGATIVE.

Number of cells analyzed: 60

% of cells positive for the ALK rearrangement: 1(1.7%)

Only split O & G (single O and single G in the same nucleus: 0%

Fusion + split O and G in the same nucleus: 0%

Only single O: 0%

Fusion + single O: 1(1.7%)

% of the cells with the normal pattern: 59(98.3%)

ALK FISH analysis was manually performed and quantitatively assessed by analysis of a minimum of 60 cells using the ALK SpectrumOrange (telomeric) and the ALK SpectrumGreen (centromeric) probes.

PROBE: c-MET*/CEP7

Cytogenetic Location: 7q31.2 / 7p11.1-q11.1

C-MET FISH STUDIES PERFORMED ON THE CARCINOMA ARE NEGATIVE FOR AMPLIFICATION.

Number of cells analyzed: 61

Ratio c-MET/CEP7: 1.04

SNR (signal to nucleus ratio): 1.9

CNR (centromere to nucleus ratio): 1.9

PROBE: FGFR1(Fibroblast Growth Factor Receptor 1)/8p11.1q11.1

FGFR1 FISH STUDIES PERFORMED ON THE CARCINOMA ARE NEGATIVE FOR AMPLIFICATION.

Number of cells analyzed: 61

Ratio FGFR1/Centromere8: 0.99

SNR (signal to nucleus ratio): 2.1

CNR (centromere to nucleus ratio): 2.1

[Handwritten signature]

[page 3 of 4]
SPECIAL PROCEDURES:
Molecular Anatomic Pathology Procedure
Interpretation

MOLECULAR ANATOMIC PATHOLOGY TESTING:

Block 6D:

- A. *EGFR* exon 18 mutation NOT identified.
- B. *EGFR* exon 19 mutation NOT identified.
- C. *EGFR* exon 20 mutation NOT identified.
- D. *EGFR* exon 21 mutation NOT identified.
- E. *KRAS* codon 12 IDENTIFIED (p.G12A, c.35G>C).
- F. *KRAS* codon 61 mutation NOT identified.
- G. *BRAF* codon 600 mutation NOT identified.

NOTE:

The quantity and quality of isolated DNA was acceptable for testing.

BACKGROUND:

EGFR mutations are present in about 10-15% of non-Asian and up to 40% of the Asian patients with non-small-cell lung cancer (NSCLC) (1,2). They are more frequent in non-smokers, females, and in tumors with adenocarcinoma histology. Activating *EGFR* mutations including exon 19 deletions, exon 21 point mutations (L858R, L861Q), and exon 18 G719A/C/S point mutation are associated with the clinical response to treatment with *EGFR* tyrosine kinase inhibitors (TKI) (gefitinib, erlotinib) (2-4). Advanced NSCLC patients with activating *EGFR* mutations show response rates of more than 70%, with progression-free survival up to 14 month (2,3). However, *EGFR* mutations in exon 20 (insertions and T790M point mutation) are associated with acquired resistance to TKIs (4). *KRAS* mutations and *BRAF* mutations are found in approximately 30% and 2% of lung adenocarcinomas respectively. The most common mutation types are *KRAS* codon 12/13 and *BRAF* V600E. Patients with these mutations tend to be resistant to erlotinib and gefitinib (2,5,6). However, not all tumors reveal such a correlation and, therefore, the results of molecular testing should be interpreted in conjunction with other laboratory and clinical findings.

MUTATIONAL ANALYSIS:

For cytology samples, extraction of DNA was performed from the fluid or sample provided. For surgical specimens, manual microdissection was performed. Specimens with the minimum of 50% of tumor cells in a microdissection target or more than 300 cells for FNA specimen were accepted for the analysis. DNA was isolated using standard laboratory procedure. Optical density readings were obtained. For the detection of mutation, DNA was amplified with primers for the exons 2 and 3 of the *KRAS* gene and exons 18-21 of the *EGFR* gene. Then, forward and reverse sequencing was performed using the BigDye Terminator Kit on ABI3130. The sequencing electropherograms were analyzed for the presence of mutations. The method sensitivity is approximately 20% of mutant alleles in a background of normal DNA. For detection of *BRAF* mutation, real-time PCR was performed on the LightCycler platform to amplify *BRAF* codons 599-601 sequences. Post-PCR melting curve analysis was used to detect possible mutations. If required, the mutation type was confirmed by sequencing of the PCR product on ABI3130. The limit of detection is approximately 10-20% of alleles with mutation present in the background of normal DNA.

[page 4 of 4]
Results

ALK translocation is detected as follows:

ALK negative:

0-15% of cells positive for the *ALK* rearrangement.

Normal cells without the *ALK* translocation show green and orange signals in juxtaposition.

ALK positive:

Greater than 15% of cells positive for the *ALK* rearrangement.

Cells with the *ALK* translocation show one of the following patterns: One pair of signals (green and orange) fused or in juxtaposition and one green and one orange signal separated; Only split O & G (single O and single G in the same nucleus); Only single O; Fusion + single O.

c-MET amplification is detected as follows:

*RP11-163C9,

c-MET FISH positive:

Gene Amplification: Ratio gene/chromosome more than two

c-MET FISH negative:

Ratio gene/chromosome less than two

FGFR1 (Fibroblast Growth Factor Receptor 1) is a protein coding gene whose largest transcript features 18 exons, measures 5.6 kb and is located on chromosome 8p11.2. The *FGFR1* probe mix consists of a green 154kb probe telomeric to the *FGFR1* gene spanning the *LETM2-202* gene and D8S135 marker. The red probe is 52kb centromeric to the *FGFR1* gene spanning a 108kb region including the D8S389 marker.

FGFR1 FISH positive:

Gene Amplification: Ratio gene/chromosome more than two

FGFR1 FISH negative:

Ratio gene/chromosome less than two

Source: NCI Genomic Data Commons file 970870f1-e930-4bad-8c29-4288f1a0cc1d (TCGA-50-8457.21529B79-5B5B-46E6-8DEB-E4E6460A4695.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).